Surgical pathology report (de-identified scan), TCGA case TCGA-AR-A1AN, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site Mayo, specimen TCGA-AR-A1AN-01A (Primary Tumor).

1CD-0-3

Carcinoma, infiltrating duct, NOS
8500/3

Site Code: breast, NOS C50.9

12/21/10 *lu*

Final Diagnosis

Breast, right, wide local excision: Infiltrating ductal carcinoma, Nottingham grade II (of III) [tubules 3/3, nuclei 3/3, mitoses 1/3; Nottingham score 7/9], forming a mass (2.2 x 1.6 x 1.6 cm) [AJCC pT2]. Ductal carcinoma in situ is absent. Angiolymphatic invasion is absent. The non-neoplastic breast parenchyma shows nonproliferative fibrocystic changes. Biopsy site changes are present. All surgical resection margins, after a separately submitted re-excision of the inferior margin, are negative for tumor (minimum tumor free margin, 0.5 cm, deep/superior margin).

Lymph nodes, right axillary sentinel, excision: Multiple (5) right axillary sentinel lymph nodes are negative for metastatic carcinoma [AJCC pN0 (i-) (sn)]. Blue dye is identified in all five right axillary sentinel lymph nodes. Immunohistochemical cytokeratin stain was performed on the paraffin embedded sentinel lymph node tissue and confirms the H&E impression.

Her-2/NEU has been ordered on paraffin-embedded tissue.

	Yes	No
Site/ID		
Primary Malignancy History		☒
Secondary/Synchronous Primary Noted		☒

Source: NCI Genomic Data Commons file 200fce8d-28cc-47df-80fa-83e3ee7d87b3 (TCGA-AR-A1AN.DA251274-7966-4F48-A02F-393ABBDAB4E9.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).